CCDI case PBBIJX — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Epithelial Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/ab33a355-8dba-4a4b-b14d-6dd394c6cf33

Demographics
Sex at birth: female; Race: white.

Diagnoses (1)
1. Dysembryoplastic neuroepithelial tumor: ICD-O-3 morphology code: 9413/0; Tissue or organ of origin: Temporal lobe; Age at diagnosis: 3.6 years (1,324 days).

Biospecimens (3 samples)
- Sample 0D9DR5: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0D9DR6: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
- Sample 0D9DR7: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
